Somatic mutation profile of tumor specimen TCGA-55-8508-01A (aliquot TCGA-55-8508-01A-11D-2393-08) from TCGA case TCGA-55-8508, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.7 years (22,159 days).
Specimen TCGA-55-8508-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f4eefe8-2713-4aa6-b460-81297328bb49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8508-10A (Blood Derived Normal), aliquot TCGA-55-8508-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d25e327-9311-47b1-aeba-9797e2a3e818

The open-access MAF lists 195 somatic variants for this specimen: 152 protein-altering or splice-affecting, 41 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 41, Nonsense Mutation 13, Frame Shift Del 9, Splice Site 3, Frame Shift Ins 1, Splice Region 1, In Frame Ins 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8494C>T p.R2832C | Missense Mutation (SNP) | VAF 47/190 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587779872, CM980159, COSV53732886, COSV53761977; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL11A2 | c.3058C>T p.R1020* (on ENST00000341947 / NM_080680.3; = p.R913* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | catalogued as rs911722283, COSV100553453; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 4/8 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913315, CM991156, COSV58820621, COSV58820976, COSV99045288; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TUBGCP4 | c.23C>A p.A8D | Missense Mutation (SNP) | VAF 3/32 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53018116; called by muse, mutect2
- AFF2 | c.286G>C p.G96R | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100648899, COSV60681975; called by muse, mutect2, varscan2
- AKAP1 | c.1361T>C p.I454T | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100027728; called by muse, mutect2, varscan2
- ALG9 | c.1185C>G p.H395Q (on ENST00000614444 / NM_001352418.1; = p.H402Q on NM_024740.2) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.863); catalogued as COSV101211849; called by muse, mutect2, varscan2
- ANK1 | c.2583G>T p.R861S | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55896390, COSV99224004; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.2950A>G p.M984V | Missense Mutation (SNP) | VAF 85/231 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV99782122; called by muse, mutect2, varscan2
- ANOS1 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as CM133694, COSV99390448; called by muse, mutect2, varscan2
- ARPP21 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV99491038; called by muse, mutect2, varscan2
- ASIC2 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.322); catalogued as rs779793341, COSV63323976; called by muse, mutect2, varscan2
- ASTN1 | c.2108C>A p.T703K | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV99920531; called by muse, mutect2, varscan2
- BANK1 | c.1461G>C p.L487F | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV100535886; called by muse, mutect2, varscan2
- BCL6 | c.1418del p.P473Rfs*117 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as COSV51655892; called by mutect2, pindel, varscan2
- CACNA2D3 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99870486; called by muse, mutect2, varscan2
- CACNB2 | c.1391C>A p.T464N (on ENST00000324631 / NM_201596.3; = p.T409N on NM_000724.4) | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs760396780, COSV99993102; called by muse, mutect2, varscan2
- CALCB | c.290T>G p.L97R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100158010; called by muse, mutect2, varscan2
- CASR | c.2031G>T p.Q677H (on ENST00000490131; = p.Q754H on NM_000388.4) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99948465; called by muse, mutect2, varscan2
- CASR | c.2032G>T p.E678* (on ENST00000490131; = p.E755* on NM_000388.4) | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV99948467; called by muse, mutect2, varscan2
- CEP128 | c.2863G>T p.V955L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV99823697; called by muse, mutect2, varscan2
- CLSTN2 | c.2332T>A p.Y778N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101515539; called by muse, mutect2, varscan2
- CNTN5 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs201986333, COSV54281395; called by muse, mutect2, varscan2
- CNTNAP5 | c.538G>T p.V180F | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV101443070; called by muse, mutect2, varscan2
- COL21A1 | c.47T>G p.L16R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV99777489; called by muse, mutect2, varscan2
- COL21A1 | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.534); catalogued as COSV55173146; called by muse, mutect2, varscan2
- COL22A1 | c.2593-1G>A p.X865_splice | Splice Site (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100276430; called by mutect2, varscan2
- CTNNA2 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV63544327; called by muse, mutect2, varscan2
- CUBN | c.10200C>A p.H3400Q | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100912070, COSV64721571; called by muse, mutect2, varscan2
- CUBN | c.1898G>T p.G633V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100912071; called by muse, mutect2, varscan2
- CXCR4 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99602519; called by muse, varscan2
- CYLC1 | c.1458G>A p.M486I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV61414198; called by muse, mutect2, varscan2
- DAPK1 | c.3509G>T p.W1170L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV100801050, COSV100801601; called by muse, mutect2, varscan2
- DAXX | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99801485; called by muse, mutect2, varscan2
- DSC2 | c.1642A>G p.T548A | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV99199482; called by muse, mutect2, varscan2
- DSCAM | c.4067A>G p.Y1356C | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs879128271, COSV101259158; called by muse, mutect2, varscan2
- DSG3 | c.518-1G>T p.X173_splice | Splice Site (SNP) | VAF 19/74 reads (26%) | catalogued as COSV99933770; called by muse, mutect2, varscan2
- ELOVL4 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as COSV100876167; called by muse, mutect2, varscan2
- ENPP2 | c.2265-1G>T p.X755_splice (on ENST00000075322 / NM_001040092.3; = p.X807_splice on NM_006209.5) | Splice Site (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99307534; called by muse, mutect2, varscan2
- ESRRB | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV99834803; called by muse, mutect2, varscan2
- FAM47A | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.973); catalogued as rs745405704, COSV60493619; called by muse, mutect2, varscan2
- FLG2 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101165596; called by muse, mutect2
- FLRT3 | c.1650G>T p.W550C | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99427193; called by muse, mutect2, varscan2
- FOXB2 | c.328A>C p.K110Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100942295; called by muse, mutect2
- FOXP2 | c.2057C>A p.P686Q | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100646235; called by muse, mutect2, varscan2
- GBE1 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | catalogued as CM128777, COSV101450088; called by muse, mutect2, varscan2
- GLDC | c.1776G>C p.Q592H | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100393809; called by muse, mutect2, varscan2
- GOLGA2 | c.1016A>T p.Q339L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV101363062; called by muse, mutect2, varscan2
- GPR15 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99423640; called by muse, mutect2, varscan2
- GPR37 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV100390543, COSV100390561; called by muse, mutect2, varscan2
- GUCY1A2 | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV99972835; called by muse, mutect2, varscan2
- GUCY1A2 | c.1695G>T p.V565= | Splice Region (SNP) | VAF 16/76 reads (21%) | catalogued as rs201999952, COSV99972837; called by muse, mutect2, varscan2
- ICE1 | c.6466G>T p.A2156S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as rs1483862890, COSV99663807; called by muse, mutect2
- IGFBP2 | c.968G>C p.R323P | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.364); catalogued as rs759413522, COSV99288284; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs752217662; called by muse, mutect2, varscan2
- IGSF10 | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1292868194, COSV99176661; called by muse, mutect2, varscan2
- INPPL1 | c.3694A>G p.T1232A | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV99995851; called by muse, mutect2, varscan2
- IQGAP3 | c.128G>A p.W43* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100752066; called by muse, mutect2, varscan2
- IQSEC1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs764778594, COSV99831332; called by muse, mutect2, varscan2
- KCNA5 | c.1489G>T p.G497C | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99363632; called by muse, mutect2, varscan2
- KCNK2 | c.685T>C p.F229L (on ENST00000444842 / NM_001017425.3; = p.F214L on NM_014217.4) | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV101221864; called by muse, mutect2, varscan2
- KIF21A | c.3678G>T p.R1226S (on ENST00000361418 / NM_001378440.1; = p.R1213S on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100735291; called by muse, mutect2, varscan2
- KIF21A | c.3677G>T p.R1226M (on ENST00000361418 / NM_001378440.1; = p.R1213M on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100735292; called by muse, mutect2, varscan2
- KL | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.425); catalogued as COSV101199006; called by muse, mutect2, varscan2
- KLF15 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV99955066; called by muse, mutect2, varscan2
- LAMC3 | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs201590096, COSV100735881, COSV100736093; called by muse, mutect2, varscan2
- LGR5 | c.1224C>A p.N408K | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99877532; called by muse, mutect2, varscan2
- LPAR4 | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV101425076; called by muse, mutect2, varscan2
- LRP1B | c.3943G>T p.G1315* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV101252832, COSV67273781; called by muse, mutect2, varscan2
- LRP1B | c.1551A>T p.K517N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV101252835; called by muse, mutect2, varscan2
- LRRC7 | c.1861G>T p.V621F (on ENST00000651989 / NM_001370785.2; = p.V588F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV99224578; called by muse, mutect2, varscan2
- LRRN1 | c.722T>A p.L241H | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100076044; called by muse, mutect2, varscan2
- LTBP2 | c.2461G>A p.G821R | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV56207539, COSV99999812; called by muse, mutect2, varscan2
- MAP3K5 | c.3178G>T p.E1060* | Nonsense Mutation (SNP) | VAF 33/212 reads (16%) | catalogued as COSV100752505; called by muse, mutect2, varscan2
- MUC16 | c.9854T>A p.L3285H | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); catalogued as COSV101198185; called by muse, mutect2, varscan2
- MYH6 | c.334T>A p.W112R | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100676306; called by muse, mutect2, varscan2
- MYH8 | c.3223G>A p.D1075N | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); catalogued as COSV67974888; called by muse, mutect2, varscan2
- NALCN | c.4518C>A p.D1506E | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV99213066; called by muse, mutect2, varscan2
- NCAM1 | c.1281G>A p.W427* (on ENST00000316851 / NM_181351.5; = p.W417* on NM_000615.7) | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100377050; called by muse, mutect2, varscan2
- NCAM2 | c.1002G>T p.W334C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521364; called by muse, mutect2, varscan2
- NEURL1 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100872659; called by muse, mutect2, varscan2
- NUP188 | c.3708G>T p.E1236D | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.113); catalogued as COSV101001199; called by muse, mutect2
- OR10AG1 | c.129C>A p.H43Q | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100399983; called by muse, mutect2, varscan2
- OR10P1 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100548105; called by muse, mutect2, varscan2
- OR2D3 | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 29/109 reads (27%) | catalogued as rs749476662, COSV53491748; called by muse, mutect2, varscan2
- OR2J2 | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.046); catalogued as COSV101013285; called by muse, mutect2
- OR2T12 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV100527535; called by muse, mutect2, varscan2
- OR2T3 | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs894331275, COSV100613079; called by muse, mutect2, varscan2
- OR52N2 | c.108G>C p.M36I | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100396040; called by muse, mutect2, varscan2
- OR5D13 | c.492T>A p.F164L | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.033); catalogued as COSV100686733; called by muse, mutect2, varscan2
- OR5I1 | c.59C>A p.P20Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100041214; called by muse, mutect2, varscan2
- PCDH10 | c.981C>G p.Y327* | Nonsense Mutation (SNP) | VAF 25/121 reads (21%) | catalogued as COSV99993006; called by muse, mutect2, varscan2
- PCDH8 | c.2047G>T p.G683C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100131227; called by muse, mutect2, varscan2
- PCF11 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV100017810; called by muse, mutect2, varscan2
- PCLO | c.9479A>T p.D3160V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100427553, COSV61662972; called by muse, mutect2
- PCLO | c.8649G>T p.W2883C | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.964); catalogued as COSV61635010; called by muse, mutect2, varscan2
- PCLO | c.1099G>C p.G367R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV100427556; called by muse, mutect2, varscan2
- PEG3 | c.4663G>T p.G1555C | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV55624721, COSV99687379; called by muse, mutect2, varscan2
- PMEL | c.1877C>T p.S626F | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); catalogued as COSV100092664; called by muse, mutect2, varscan2
- PNLIPRP1 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564039624, COSV100724264; called by muse, mutect2, varscan2
- PPEF1 | c.1838A>T p.K613M | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV100583568; called by muse, mutect2, varscan2
- PRDM9 | c.709C>A p.R237S | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs1187228739, COSV99689805, COSV99689896; called by muse, mutect2
- PTCRA | c.153T>A p.D51E | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV100485703; called by muse, mutect2
- RAPGEF4 | c.2563A>T p.K855* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV99909788; called by muse, mutect2, varscan2
- RB1CC1 | c.4541G>T p.R1514L | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV99206260; called by muse, mutect2, varscan2
- ROBO1 | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101458309; called by muse, mutect2, varscan2
- RPTOR | c.3229A>G p.N1077D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100155129; called by muse, mutect2, varscan2
- SCML2 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV52618740, COSV99318575; called by muse, varscan2
- SEMA3E | c.1797G>T p.L599F | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV57103467; called by muse, mutect2
- SEMA5A | c.1332G>C p.L444F | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV101227130, COSV66796236; called by muse, mutect2, varscan2
- SIM1 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53494232, COSV99491940; called by muse, mutect2, varscan2
- SLC35A4 | c.764T>A p.L255H | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100021103, COSV60052677; called by muse, mutect2, varscan2
- SLC5A1 | c.1693A>T p.N565Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV99833207; called by muse, mutect2, varscan2
- SLIT2 | c.3902G>T p.G1301V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.279); catalogued as COSV99881029; called by muse, mutect2, varscan2
- SMARCA2 | c.2481G>T p.L827F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100570319; called by muse, mutect2, varscan2
- SMARCA2 | c.4214A>G p.K1405R | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.678); catalogued as COSV100190131; called by muse, mutect2, varscan2
- SPATA31A3 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs577754236; called by muse, mutect2, varscan2
- SPATA4 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as COSV99708801; called by muse, mutect2
- SPEM1 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs759550542, COSV100080808; called by muse, mutect2, varscan2
- SPTA1 | c.6127G>T p.D2043Y | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs779411955, COSV100934285; called by muse, mutect2, varscan2
- SVEP1 | c.3637C>T p.R1213C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.657); catalogued as rs185467075, COSV57035639; called by muse, mutect2, varscan2
- TGM7 | c.1886C>T p.T629I | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.522); catalogued as COSV101476820; called by muse, mutect2, varscan2
- TMCO2 | c.240A>C p.K80N | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as COSV101033722; called by muse, mutect2, varscan2
- TMEM59L | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99449993; called by muse, mutect2
- TPK1 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV100765327, COSV63645742; called by muse, mutect2, varscan2
- TROAP | c.1363G>A p.V455I | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99226669; called by muse, mutect2, varscan2
- TTC29 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV100283223; called by muse, mutect2, varscan2
- UACA | c.3278A>C p.N1093T | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV100537264; called by muse, mutect2, varscan2
- UGT2A1 | c.745G>C p.G249R | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV99683847; called by muse, mutect2, varscan2
- UGT2B11 | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101485218; called by muse, mutect2
- USH2A | c.6741del p.A2249Pfs*30 | Frame Shift Del (DEL) | VAF 39/372 reads (10%) | catalogued as rs1335175914; called by mutect2, pindel, varscan2
- USH2A | c.116G>T p.R39M | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100229230; called by muse, mutect2, varscan2
- ZFHX4 | c.6800C>A p.T2267N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); catalogued as COSV99256486, COSV99260930; called by muse, mutect2, varscan2
- ZIC1 | c.1177C>A p.P393T | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV99291549; called by muse, mutect2, varscan2
- ZNF107 | c.1661G>A p.C554Y | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs748783670, COSV100788222; called by muse, mutect2, varscan2
- ZNF229 | c.335T>A p.V112E | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV99350054; called by muse, mutect2, varscan2
- ZNF43 | c.324A>C p.E108D | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100731689; called by muse, mutect2, varscan2
- ZNF773 | c.67T>C p.Y23H | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99989086; called by muse, mutect2, varscan2
- ZNF8 | c.1166G>T p.R389I | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99544113; called by muse, mutect2, varscan2
- ABCB4 | c.2454del p.T819Qfs*16 | Frame Shift Del (DEL) | VAF 7/84 reads (8%) | called by mutect2, pindel
- DBNL | c.448del p.Q150Rfs*132 (on ENST00000448521 / NM_001014436.3; = p.Q150Rfs*133 on NM_014063.7) | Frame Shift Del (DEL) | VAF 15/114 reads (13%) | called by mutect2, pindel, varscan2
- FAM47A | c.1228del p.H410Ifs*20 | Frame Shift Del (DEL) | VAF 38/114 reads (33%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.277C>G p.P93A | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIAA0319L | c.109dup p.C37Lfs*15 | Frame Shift Ins (INS) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- KIR2DL4 | c.707G>T p.G236V (on ENST00000396284; = p.G197V on NM_001080770.2) | Missense Mutation (SNP) | VAF 86/352 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- NAV3 | c.3454del p.R1152Efs*27 | Frame Shift Del (DEL) | VAF 35/89 reads (39%) | called by mutect2, pindel, varscan2
- NBPF11 | c.909A>C p.K303N | Missense Mutation (SNP) | VAF 147/501 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OTOA | c.547del p.V183Cfs*2 | Frame Shift Del (DEL) | VAF 29/98 reads (30%) | called by mutect2, pindel, varscan2
- PLEC | c.8376_8409del p.Q2793Rfs*37 (on ENST00000322810 / NM_201380.4; = p.Q2683Rfs*37 on NM_000445.5) | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel
- SGIP1 | c.1460del p.P487Lfs*11 | Frame Shift Del (DEL) | VAF 27/188 reads (14%) | called by mutect2, pindel, varscan2
- UBC | c.506_508dup p.V169dup | In Frame Ins (INS) | VAF 78/237 reads (33%) | called by mutect2, pindel, varscan2
- AKAP1 | c.1362C>A p.I454= | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as COSV100027729; called by muse, mutect2, varscan2
- ANO5 | c.681C>T p.G227= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs547557493, COSV100201421; called by muse, mutect2, varscan2
- ARFGEF1 | c.2862G>T p.T954= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV99141113; called by muse, mutect2, varscan2
- ASB2 | c.1749C>T p.Y583= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs770176666, COSV100279229; called by muse, mutect2, varscan2
- AVPR2 | c.261C>A p.A87= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100509409, COSV61686049; called by muse, mutect2, varscan2
- BRINP3 | c.1293C>T p.D431= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV100818368; called by muse, mutect2
- C2orf49 | c.390G>A p.P130= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs780814726, COSV99307396; called by muse, mutect2, varscan2
- CCDC144A | c.3204G>A p.K1068= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV100138341; called by muse, mutect2, varscan2
- COPB1 | c.2526G>A p.Q842= | Silent (SNP) | VAF 30/158 reads (19%) | catalogued as COSV99999271; called by muse, mutect2, varscan2
- DHX57 | c.1728A>G p.Q576= | Silent (SNP) | VAF 100/196 reads (51%) | catalogued as COSV99769088; called by muse, mutect2, varscan2
- EPHA5 | c.2166A>T p.L722= | Silent (SNP) | VAF 37/197 reads (19%) | catalogued as COSV99896302; called by muse, mutect2, varscan2
- FAM47C | c.249C>T p.L83= | Silent (SNP) | VAF 56/133 reads (42%) | catalogued as COSV100792212, COSV100792282, COSV63725589; called by muse, mutect2, varscan2
- GALNT6 | c.1149C>T p.N383= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs138065864; called by muse, mutect2, varscan2
- GAS2 | c.483G>C p.V161= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV99534703; called by muse, mutect2, varscan2
- IL15RA | c.402C>T p.P134= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV101181678; called by muse, mutect2
- JPH1 | c.804G>T p.P268= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as rs1563424504, COSV100646433, COSV60615274; called by muse, mutect2, varscan2
- MAGEC1 | c.3099G>A p.E1033= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as COSV53575435, COSV53580421; called by muse, mutect2, varscan2
- MAP1S | c.2607C>T p.P869= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100140817; called by muse, mutect2, varscan2
- MRAS | c.588G>T p.R196= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100003559; called by muse, mutect2
- MS4A7 | c.366A>T p.A122= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV100279354; called by muse, mutect2, varscan2
- MUC16 | c.12375G>A p.T4125= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV101198184; called by muse, mutect2, varscan2
- OR10K1 | c.840C>A p.I280= | Silent (SNP) | VAF 49/183 reads (27%) | catalogued as COSV56872814, COSV99193223; called by muse, mutect2, varscan2
- OR2T12 | c.756T>C p.A252= | Silent (SNP) | VAF 19/184 reads (10%) | catalogued as COSV100527536; called by muse, mutect2, varscan2
- OR4A16 | c.858G>T p.S286= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV59042945, COSV59044738; called by muse, mutect2, varscan2
- OR4L1 | c.228C>A p.A76= | Silent (SNP) | VAF 58/184 reads (32%) | catalogued as COSV100235563, COSV59851419; called by muse, mutect2, varscan2
- OR4P4 | c.24T>A p.T8= | Silent (SNP) | VAF 20/184 reads (11%) | catalogued as COSV100111557; called by muse, mutect2, varscan2
- PCDHA9 | c.2283C>A p.G761= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs371734141, COSV100969047; called by muse, mutect2, varscan2
- PNKP | c.97C>T p.L33= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs778423306, COSV100464861; called by muse, varscan2
- PNLIPRP1 | c.738C>G p.P246= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV100724265, COSV62613507; called by muse, mutect2, varscan2
- POU2AF1 | c.49C>A p.R17= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1327122899, COSV101260516; called by muse, mutect2, varscan2
- PRKRIP1 | c.109C>A p.R37= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100700311; called by muse, mutect2, varscan2
- PTPRF | c.3268C>T p.L1090= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV100740604; called by muse, mutect2, varscan2
- PTPRZ1 | c.6723C>T p.H2241= | Silent (SNP) | VAF 53/150 reads (35%) | catalogued as COSV101099594, COSV66440492; called by muse, mutect2, varscan2
- RAPGEF2 | c.1776A>T p.S592= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV100030549; called by muse, mutect2, varscan2
- RBM6 | c.2031G>A p.E677= | Silent (SNP) | VAF 43/243 reads (18%) | catalogued as COSV99804569; called by muse, mutect2, varscan2
- SLC4A2 | c.1737C>T p.L579= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs763097239, COSV100054862; called by muse, mutect2, varscan2
- SORBS3 | c.111G>C p.V37= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV99530940; called by muse, varscan2
- SSRP1 | c.1534C>A p.R512= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV99554738; called by muse, mutect2, varscan2
- TMEM241 | c.579G>T p.L193= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV101271692; called by muse, mutect2, varscan2
- TRPC7 | c.1686C>T p.N562= | Silent (SNP) | VAF 24/149 reads (16%) | catalogued as rs575067864, COSV61457584; called by muse, mutect2, varscan2
- ZNF317 | c.852A>G p.G284= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV56112140; called by muse, mutect2
- FAM27E5 | n.470G>C | RNA (SNP) | VAF 6/54 reads (11%) | catalogued as rs1396084703; called by muse, mutect2
- ZNFX1 | chr20:49280340 G>A | 5'Flank (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
